TCGA case TCGA-DB-5277 — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Mayo Clinic - Rochester. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d05079f2-9883-46e6-ad06-9e561f08d819

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 34 years; Vital status: Dead; Days to death: 1,547 days (4.2 years).

Diagnoses (2)
1. Astrocytoma, anaplastic (the primary disease): ICD-O-3 morphology code: 9401/3; ICD-10 code: C71.0; Tissue or organ of origin: Cerebrum; Site of resection or biopsy: Nervous system, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 34.8 years (12,725 days); Year of diagnosis: 2007; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,547 days (4.2 years); First symptom longest duration: 0-30 Days; First symptom prior to diagnosis: Seizures; Sites of involvement: Brain, Frontal lobe; Supratentorial localization: Cerebral Cortex.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 26 days; Days to treatment end: 71 days; Treatment dose: 5,940 cGy; Course number: 1; Number of fractions: 33; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 27 days; Days to treatment end: 61 days; Number of cycles: 5; Treatment dose: 5,250 mg; Prescribed dose: 75; Prescribed dose units: mg/m2/day; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 91 days; Days to treatment end: 361 days; Number of cycles: 9; Treatment dose: 9,900 mg; Prescribed dose: 110; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 1,117 days (3.1 years); Days to treatment end: 1,239 days (3.4 years); Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Progressive Disease; Days to treatment start: 1,148 days (3.1 years); Treatment dose: 5,600 cGy; Course number: 2; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Antiseizure Treatment; Timepoint category: Preoperative.
   Recorded as not given: Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis; Steroid Therapy, preoperative.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 38.0 years (13,881 days); Days to diagnosis: 1,156 days (3.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Surgery, NOS to Locoregional Site.

Follow-up (3 entries)
- Day 1,156 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 1,419 days (3.9 years); Disease response: With Tumor.
- Days to follow up: 1,547 days (4.2 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Allergies; Risk factors: Allergy, Seafood.
- Timepoint category: Prior to Diagnosis; Comorbidities: Eczema / Allergies; Risk factors: Eczema / Hay Fever / Allergy, Mold or Dust.
- Timepoint category: Prior to Diagnosis; Risk factors: Headache / Seizure.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DB-5277-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.5; Intermediate dimension: 1; Shortest dimension: 0.1.
  Slide TCGA-DB-5277-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-DB-5277-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-DB-5277-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DB-5277-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Astrocytoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; History ionizing radiation to head: No; Tumor status: With tumor; Tumor site: Supratentorial, Frontal Lobe; History seizures: Yes; History headaches: Yes; Symp changes mental status: No; Symp changes visual: No; Symp changes sensory: No; Symp changes motor movement: No; First symptom longest duration: 0 - 30 Days; History asthma: No; History eczema: Yes; Histor hay fever: Yes; History dust mold allergy: Yes; Allergy food diagnosis indicator: Yes; Allergy food diagnosis type: seafood; History neoadjuvant steroid treatment: No; History neoadjuvant medication: Yes; Family history brain tumor: No; Inherited genetic syndrome indicator: No.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: Temodar.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 3: Regimen number: 2; Pharmaceutical therapy drug name: Temozolamide; Therapy regimen: Progression.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: Yes; New tumor event surgery: No; Tumor status: With tumor; New tumor event pharmaceutical treatment: Yes; New tumor event radiation treatment: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,547 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,547 days; disease-free interval: event (new tumor event after initially disease-free), 1,156 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,156 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DB-5277-01A-01D-1466-01): tumor purity 0.9, ploidy 1.8, whole-genome doublings 0.
